Surgical pathology report (de-identified scan), TCGA case TCGA-44-A47A, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-A47A-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

ICD-O-3

adenocarcinoma, NOS

8/40/3

Site: lung, upper lobe

9-5-12

RD

c34.1

Procedure:

Diagnosis

A. Lung, right upper lobe, resection: Moderately differentiated adenocarcinoma

B. Lymph nodes, R4, biopsy: There is no evidence of malignancy in any of 4 lymph nodes.

C. Lymph nodes, level X, biopsy: There is no evidence of malignancy in either of 2 lymph nodes.

D. Lymph nodes, level VII, biopsy: There is no evidence of malignancy in any of 6 lymph nodes.

Microscopic Description:

A.

Histologic type: Adenocarcinoma

Histologic grade: 2 of 3

Mitotic index: 4 Mitoses/10 HPFs (1 HPF = 0.23 sq. mm)

Tumor size: 3.7 cm

Bronchial resection margin: Negative for malignancy

Pulmonary margin of resection: Negative for malignancy

Pleura: Negative for malignancy

Vascular invasion: Absent

Attached lymph nodes: Two lymph nodes, negative for malignancy

pTNM stage: T2a N0

Non-tumorous lung: Emphysema

There is a portion of the tumor with a more solid appearance (A6), but the immunohistochemical staining pattern is compatible with adenocarcinoma.

Antibody...Results...Comment

TTF-1 ...Positive

CK5/6 ...Negative

.p63 ...Weakly positive

Paraffin sections; 10% neutral buffered formalin; Controls stain appropriately.

[A few of the antibodies used in our laboratory may be classified as analyte specific reagents.

These antibodies are monitored and controlled in our laboratory and their performance for

in vitro diagnosis is well described in the medical literature.

They have not been cleared

or approved by the FDA.]

Specimen

A. Right upper lobe

B. R4 lymph node

C. Level X node

D. Level VII lymph node

Clinical Information

Lung cancer

[page 2 of 2]
Gross Description

A. The specimen is received unfixed labeled right upper lobe and consists of a 174 g lung lobe measuring 13.5 by 10 by 4 cm. There is a stapled margin on one side of the specimen. There is a palpable mass at one pole the specimen. On cut section the mass measures 3.7 by 3.5 cm in greatest cross sectional dimension. A portion of the specimen is taken for research purposes. Sections after fixation. RS11

B. The specimen is received unfixed labeled R4 lymph node and consists of 3 pieces of black soft tissue measuring 1.5, 0.6 and 0.5 cm in greatest dimension. AS-1

Specimen C. is received unfixed labeled level 10 node and consists of 5 pieces of tan and black soft tissue occupying approximately 1.5 mL in volume. AS-1

Specimen D. is received unfixed labeled level 7 lymph node and consists of 4 pieces of black soft tissue measuring 1.4 cm in greatest aggregate dimension. AS-1

Diagnostic Discrepancy		
Metastatic/Synchronous Primary Noted		

8/22/12

Source: NCI Genomic Data Commons file b1398005-7257-4367-acd7-ab46236c9cc5 (TCGA-44-A47A.3F92B4C0-ED5F-486D-A751-730136B1D9A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).